Somatic mutation profile of tumor specimen TARGET-20-PARJWH-09A (aliquot TARGET-20-PARJWH-09A-01D) from TARGET case TARGET-20-PARJWH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (349 days).
Specimen TARGET-20-PARJWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f66573b-047c-4f16-a3c0-28bf72b56081.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJWH-14A (Bone Marrow Normal), aliquot TARGET-20-PARJWH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3be6f8b8-4bbd-416d-9719-e07d4c5de827

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 104/359 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPI1 | c.714G>A p.T238= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as rs1285833221; called by muse, mutect2, varscan2
